Somatic mutation profile of tumor specimen TARGET-20-PARHVI-03A (aliquot TARGET-20-PARHVI-03A-02D) from TARGET case TARGET-20-PARHVI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.4 years (6,006 days).
Specimen TARGET-20-PARHVI-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2024ce4f-7756-4e94-9065-551134b5ff8e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARHVI-14A (Bone Marrow Normal), aliquot TARGET-20-PARHVI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/035a5896-eb40-4b41-bd9f-5afffabb4796

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1096-1G>T p.X366_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as rs397517076, CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; ClinVar: pathogenic; called by mutect2, varscan2
- BCORL1 | c.2130delinsTTA p.S711* | Frame Shift Ins (INS) | VAF 38/61 reads (62%) | catalogued as COSV54390341, COSV99498296; called by mutect2*, pindel, varscan2*
- BCORL1 | c.2129_2130insTT p.T712Afs*20 | Frame Shift Ins (INS) | VAF 30/51 reads (59%) | called by mutect2, varscan2
